Somatic mutation profile of tumor specimen ALCH-B2XW-TTP1-A (aliquot ALCH-B2XW-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B2XW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.6 years (24,328 days).
Specimen ALCH-B2XW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f2eebbd-c6c9-4f1f-9463-0049798b3985.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2XW-NB1-A (Blood Derived Normal), aliquot ALCH-B2XW-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b1b78db-fa2c-44ae-88aa-ed126f50c09c

The open-access MAF lists 360 somatic variants for this specimen: 235 protein-altering or splice-affecting, 87 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 87, Nonsense Mutation 19, Intron 14, RNA 7, Splice Site 6, Frame Shift Del 6, 5'UTR 5, Splice Region 5, 3'Flank 4, 3'UTR 4, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 115/432 reads (27%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NPC1 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs774333145, CM053352; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 23/135 reads (17%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.5429A>G p.Y1810C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs778749471; called by muse, mutect2, varscan2
- ANKRD30B | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.661); catalogued as rs1237576841, COSV100746000; called by muse, mutect2, varscan2
- AQP8 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 56/258 reads (22%) | catalogued as rs1420606861; called by muse, mutect2, varscan2
- ARHGEF16 | c.1573A>G p.T525A | Missense Mutation (SNP) | VAF 47/477 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as rs770242146; called by muse, mutect2, varscan2
- ASB12 | c.553del p.L185Sfs*59 | Frame Shift Del (DEL) | VAF 51/157 reads (32%) | catalogued as COSV62856598; called by mutect2, pindel, varscan2
- CA4 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 79/686 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748937172; called by muse, mutect2, varscan2
- CD79B | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 74/663 reads (11%) | catalogued as COSV50075959, COSV50076941; called by muse, mutect2, varscan2
- CIBAR1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.262); catalogued as rs1215667615; called by muse, mutect2
- CLEC1A | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.436); catalogued as rs147882348, COSV100191187, COSV59531017; called by muse, mutect2, varscan2
- CMA1 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1462507754; called by muse, mutect2, varscan2
- COL6A6 | c.3403G>A p.V1135M | Missense Mutation (SNP) | VAF 26/341 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs369579926; called by muse, mutect2
- CORO2B | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55951812; called by muse, mutect2, varscan2
- CREBBP | c.6196G>T p.A2066S | Missense Mutation (SNP) | VAF 73/956 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52133206; called by muse, mutect2
- CROCC | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 52/584 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs774725309; called by muse, mutect2
- CSN3 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); catalogued as rs372244908; called by muse, mutect2, varscan2
- DYNC2H1 | c.12419A>T p.Y4140F | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.264); catalogued as rs1452959128; called by muse, mutect2, varscan2
- E2F7 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 109/308 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV59740954; called by muse, mutect2, varscan2
- EBF1 | c.567A>T p.K189N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100565819; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV100668865; called by muse, mutect2
- ELAPOR2 | c.2234G>T p.G745V (on ENST00000450689 / NM_001142749.3; = p.G578V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV51885570; called by muse, mutect2, varscan2
- FAM13B | c.487C>A p.H163N | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs978155588; called by muse, mutect2, varscan2
- FREM3 | c.2401C>T p.Q801* | Nonsense Mutation (SNP) | VAF 69/332 reads (21%) | catalogued as COSV61682246; called by muse, mutect2, varscan2
- GART | c.1021A>T p.S341C | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777755921, COSV100738144; called by muse, mutect2, varscan2
- GIMAP4 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 70/264 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs745883640; called by muse, mutect2, varscan2
- GRAMD4 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV63029809; called by muse, mutect2, varscan2
- GRIK4 | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV101483839; called by muse, mutect2, varscan2
- GRM5 | c.1656C>G p.C552W | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59594335; called by muse, mutect2, varscan2
- HCN4 | c.1814C>A p.T605K | Missense Mutation (SNP) | VAF 92/375 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56082458, COSV56086645; called by muse, mutect2, varscan2
- IL4R | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs770914613; called by muse, mutect2
- KIF26A | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 25/140 reads (18%) | catalogued as rs1264284842, COSV59465581; called by muse, mutect2, varscan2
- KRTAP5-3 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 55/431 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.367); catalogued as COSV101294515; called by muse, mutect2, varscan2
- LRP1B | c.12116G>T p.G4039V | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV67216291, COSV67249502; called by muse, mutect2, varscan2
- LRP1B | c.4484C>A p.A1495D | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67197199; called by muse, mutect2, varscan2
- LRP1B | c.332T>A p.V111E | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.095); catalogued as rs773570931; called by muse, mutect2, varscan2
- LRRTM3 | c.902G>T p.W301L | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV63673237; called by muse, mutect2, varscan2
- MAGEC3 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as COSV74217371; called by muse, mutect2, varscan2
- MYBPC2 | c.3067A>C p.N1023H | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV63099991; called by muse, mutect2, varscan2
- MYT1L | c.1901A>G p.K634R | Missense Mutation (SNP) | VAF 89/495 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs200720795; called by muse, mutect2, varscan2
- NLRP5 | c.3470G>T p.G1157V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66766171; called by muse, mutect2, varscan2
- NOVA1 | c.545C>G p.T182R | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57490852; called by muse, mutect2
- NPAP1 | c.2860G>T p.A954S | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.047); catalogued as COSV61504684; called by muse, mutect2, varscan2
- OPCML | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100102181; called by muse, mutect2
- OR14A16 | c.538C>A p.P180T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62926133; called by muse, mutect2, varscan2
- OR4K15 | c.1019G>T p.R340I (on ENST00000305051; = p.R316I on NM_001005486.1) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1304478044; called by muse, mutect2, varscan2
- OR4N2 | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 83/692 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60050580; called by muse, mutect2, varscan2
- PC | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.3); catalogued as rs1347115049, COSV63079020; called by muse, mutect2, varscan2
- PRDM9 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 54/449 reads (12%) | catalogued as COSV57002152; called by muse, mutect2, varscan2
- PTEN | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.096); catalogued as rs551221430, COSV64294722, COSV64302290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PYHIN1 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63723263; called by muse, mutect2, varscan2
- RHAG | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 122/347 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as CM961249; called by muse, mutect2, varscan2
- RIMS2 | c.1199G>T p.R400L (on ENST00000666250 / NM_001348490.2; = p.R208L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51669256, COSV51723221; called by muse, mutect2
- RUNX1T1 | c.1206A>T p.L402F (on ENST00000265814 / NM_001198628.1; = p.L375F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/587 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as COSV56145806; called by muse, mutect2
- SI | c.478T>A p.F160I | Missense Mutation (SNP) | VAF 41/608 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); catalogued as COSV100017563; called by muse, mutect2
- SIGLEC10 | c.1709+2T>C p.X570_splice | Splice Site (SNP) | VAF 66/237 reads (28%) | catalogued as rs768101550; called by muse, mutect2, varscan2
- SIM1 | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs776861600, COSV53497878, COSV99492589; called by muse, mutect2, varscan2
- SLC5A3 | c.1767del p.K590Nfs*18 | Frame Shift Del (DEL) | VAF 13/143 reads (9%) | catalogued as COSV62968703; called by mutect2, pindel
- SLC7A13 | c.293G>C p.W98S | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99878305; called by muse, mutect2, varscan2
- SPACA1 | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.592); catalogued as rs769128092, COSV52761633; called by muse, mutect2, varscan2
- SPATA31A6 | c.2234G>T p.R745L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV60534489; called by mutect2, varscan2
- SPATA48 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.89); catalogued as rs781401342, COSV51670914; called by muse, mutect2, varscan2
- STK17B | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV55829062; called by muse, mutect2, varscan2
- SYNPO | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67784804; called by muse, mutect2, varscan2
- TBC1D2 | c.2617T>A p.F873I (on ENST00000465784 / NM_001267571.2; = p.F862I on NM_018421.4) | Missense Mutation (SNP) | VAF 73/462 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV59788556; called by muse, mutect2, varscan2
- TCHH | c.3928C>A p.R1310S | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV64274999; called by muse, mutect2
- TEKT5 | c.646del p.R216Gfs*6 | Frame Shift Del (DEL) | VAF 44/211 reads (21%) | catalogued as COSV51587347; called by mutect2, pindel, varscan2
- TEX13C | c.2944C>A p.R982S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.799); catalogued as COSV101084716; called by muse, mutect2, varscan2
- TNNC1 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 167/618 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs750978833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM49 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs151026511, COSV61670680, COSV61672380; called by muse, mutect2
- TRIM58 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.188); catalogued as COSV63569662; called by muse, mutect2, varscan2
- TVP23A | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 85/296 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as COSV55410147; called by muse, mutect2, varscan2
- WDR70 | c.47del p.G16Dfs*52 | Frame Shift Del (DEL) | VAF 94/477 reads (20%) | catalogued as rs1255012649; called by mutect2, pindel, varscan2
- WHRN | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 123/424 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54328122; called by muse, mutect2, varscan2
- ZFHX4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.996); catalogued as rs768970618, COSV99261781, COSV99266145; called by muse, mutect2
- ZIC4 | c.395G>T p.W132L | Missense Mutation (SNP) | VAF 68/407 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67171091; called by muse, mutect2, varscan2
- ZIM3 | c.681C>A p.N227K | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54140038; called by muse, mutect2
- ZNF687 | c.2986C>G p.R996G | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV55018034; called by muse, mutect2, varscan2
- AICDA | c.82T>A p.Y28N | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AIF1 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.937); called by muse, mutect2
- ANO5 | c.2027C>T p.T676I | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- AP002495.1 | c.410G>T p.R137L (on ENST00000528511; = p.R68L on NM_001375848.1) | Missense Mutation (SNP) | VAF 36/375 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2
- ARAP2 | c.3830G>C p.G1277A | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP15 | c.214A>T p.I72F | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ARL10 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATP6V1B1 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ATP6V1G1 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- B3GAT1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 80/341 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BICD2 | c.2258+1G>T p.X753_splice | Splice Site (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- BNC1 | c.1955G>T p.G652V | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- BRINP3 | c.2116A>T p.I706F | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- C1QTNF8 | c.100T>C p.W34R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.134); called by muse, mutect2
- C1orf105 | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- C6 | c.1030C>A p.H344N | Missense Mutation (SNP) | VAF 49/522 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2
- CASKIN2 | c.1766T>C p.L589P | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- CCDC141 | c.4447G>T p.A1483S | Missense Mutation (SNP) | VAF 89/470 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCNB3 | c.4084T>G p.S1362A | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- CCND2 | c.864C>A p.D288E | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CD36 | c.851A>T p.N284I | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CDH11 | c.2118dup p.G707Wfs*13 | Frame Shift Ins (INS) | VAF 46/186 reads (25%) | called by pindel, varscan2
- CELF6 | c.1318+2T>C p.X440_splice | Splice Site (SNP) | VAF 38/184 reads (21%) | called by muse, mutect2
- CENPT | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP92 | c.2042C>G p.T681S | Missense Mutation (SNP) | VAF 171/547 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- CFTR | c.1615A>G p.I539V | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD7 | c.6361G>T p.E2121* | Nonsense Mutation (SNP) | VAF 396/1142 reads (35%) | called by muse, mutect2, varscan2
- CLCN2 | c.1856-3del | Splice Region (DEL) | VAF 125/445 reads (28%) | called by mutect2, pindel, varscan2
- CLCN5 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLGN | c.1332G>C p.W444C | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNTNAP2 | c.190A>T p.K64* | Nonsense Mutation (SNP) | VAF 58/291 reads (20%) | called by muse, mutect2, varscan2
- COG2 | c.1043T>C p.M348T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- COL6A5 | c.1215C>A p.Y405* | Nonsense Mutation (SNP) | VAF 40/128 reads (31%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2530G>T p.A844S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.038); called by muse, mutect2
- DCDC1 | c.4592T>G p.L1531R (on ENST00000597505 / NM_001367979.1; = p.L638R on NM_020869.3) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DDX3X | c.1495G>T p.V499L (on ENST00000399959; = p.V500L on NM_001356.5) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- DMD | c.3216G>T p.K1072N | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH6 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- DNER | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPPA4 | c.4T>A p.L2M | Missense Mutation (SNP) | VAF 59/337 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DZIP1 | c.1598G>A p.S533N (on ENST00000347108; = p.S514N on NM_014934.5) | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELL3 | c.389T>G p.L130R | Missense Mutation (SNP) | VAF 59/497 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ERC2 | c.2287A>C p.K763Q | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAM240C | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM53A | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- FAM90A27P | n.315+3C>T | Splice Region (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- FGF9 | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FRY | c.5944T>C p.F1982L | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FUT4 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FZD2 | c.1647G>T p.R549S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GALNT3 | c.1093G>T p.G365* | Nonsense Mutation (SNP) | VAF 48/298 reads (16%) | called by muse, mutect2, varscan2
- GATA1 | c.76T>A p.S26T | Missense Mutation (SNP) | VAF 87/182 reads (48%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- GET3 | c.770A>G p.E257G | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLYATL1 | c.744G>C p.M248I (on ENST00000317391 / NM_001354699.1; = p.M279I on NM_080661.4) | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- GOLGA8S | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- GPLD1 | c.1930A>G p.M644V | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GPR65 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- GPR89B | c.1282G>T p.V428L | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- GPS2 | c.635-3C>T | Splice Region (SNP) | VAF 51/176 reads (29%) | called by muse, mutect2, varscan2
- GRIK2 | c.570A>T p.K190N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- GRIK2 | c.1769A>T p.Y590F | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); called by muse, mutect2
- HCN1 | c.1425A>T p.L475F | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.062); called by muse, mutect2
- HEATR6 | c.1760del p.G587Efs*3 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- HELZ | c.3262C>T p.Q1088* | Nonsense Mutation (SNP) | VAF 53/288 reads (18%) | called by muse, mutect2, varscan2
- HEPHL1 | c.2360A>T p.Y787F | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- HP | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HPS3 | c.1401-1G>T p.X467_splice | Splice Site (SNP) | VAF 42/175 reads (24%) | called by muse, mutect2, varscan2
- IGLV5-37 | c.9G>C p.W3C | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- INPP5D | c.1288G>A p.G430R (on ENST00000445964 / NM_001017915.3; = p.G429R on NM_005541.5) | Missense Mutation (SNP) | VAF 100/573 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IQUB | c.1902G>T p.E634D | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2
- ITIH5 | c.2314G>A p.V772M | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR2 | c.7435T>G p.C2479G | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- ITSN2 | c.938A>T p.K313I | Missense Mutation (SNP) | VAF 56/300 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- JAKMIP3 | c.1087A>C p.K363Q | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCNJ2 | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 95/366 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- KIF5C | c.1153A>T p.K385* | Nonsense Mutation (SNP) | VAF 33/128 reads (26%) | called by muse, mutect2, varscan2
- KIF6 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIR3DL1 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 58/805 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- LAIR1 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 92/297 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- LILRB3 | c.295C>A p.H99N | Missense Mutation (SNP) | VAF 87/701 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, varscan2
- LIPC | c.856T>C p.F286L | Missense Mutation (SNP) | VAF 78/585 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- LRIG3 | c.1979T>G p.V660G | Missense Mutation (SNP) | VAF 121/483 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LRRC31 | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2
- LRRC69 | c.177G>T p.L59F | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LZTS3 | c.1798G>T p.E600* (on ENST00000329152; = p.E554* on NM_001282533.2) | Nonsense Mutation (SNP) | VAF 63/378 reads (17%) | called by muse, mutect2, varscan2
- MBOAT1 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2
- MCMDC2 | c.1553T>G p.L518W | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- MIIP | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MKRN3 | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRC1 | c.2858G>T p.S953I | Missense Mutation (SNP) | VAF 44/281 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MROH6 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- MUC3A | c.7361C>G p.T2454R | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MYO18A | c.5902G>T p.G1968* | Nonsense Mutation (SNP) | VAF 34/177 reads (19%) | called by muse, mutect2, varscan2
- MYO18A | c.3962G>T p.R1321L | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAALAD2 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NALCN | c.2576A>T p.N859I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NCKAP5 | c.3557A>G p.N1186S | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- NFKBIE | c.1258G>T p.V420L (on ENST00000275015; = p.V281L on NM_004556.3) | Missense Mutation (SNP) | VAF 29/307 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- NKX1-2 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); called by muse, mutect2
- NOTCH1 | c.1902A>T p.T634= | Splice Region (SNP) | VAF 123/446 reads (28%) | called by muse, mutect2, varscan2
- NPLOC4 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 80/358 reads (22%) | called by muse, mutect2, varscan2
- NYX | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OBSCN | c.23684G>A p.G7895E | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); called by muse, mutect2
- OR10K1 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- OR11H12 | c.892C>G p.P298A | Missense Mutation (SNP) | VAF 30/604 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2T4 | c.533C>A p.S178* | Nonsense Mutation (SNP) | VAF 100/419 reads (24%) | called by muse, mutect2, varscan2
- OR4C15 | c.101T>G p.L34R | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); called by muse, mutect2
- OR4F6 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); called by muse, mutect2
- OR4Q3 | c.291G>C p.Q97H | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- OR51A4 | c.784G>T p.V262F | Missense Mutation (SNP) | VAF 47/436 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2
- OR8B4 | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); called by muse, mutect2
- OSBPL7 | c.2502del p.N835Tfs*73 | Frame Shift Del (DEL) | VAF 39/212 reads (18%) | called by mutect2, varscan2
- PBXIP1 | c.1884G>A p.W628* | Nonsense Mutation (SNP) | VAF 53/224 reads (24%) | called by muse, mutect2, varscan2
- PEG3 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- POTEB3 | c.1353G>T p.K451N | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2
- POU3F3 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, varscan2
- PRKG1 | c.949A>T p.T317S | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PTPN13 | c.5932G>C p.V1978L (on ENST00000411767 / NM_080683.3; = p.V1959L on NM_006264.3) | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF6 | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- RUFY2 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SAMD9L | c.3881A>G p.K1294R | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SCN1A | c.2458A>T p.I820F (on ENST00000303395 / NM_001202435.3; = p.I809F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/304 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, varscan2
- SERPINA3 | c.711G>T p.K237N | Missense Mutation (SNP) | VAF 54/459 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- SERPINA7 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SIRPG | c.269C>A p.T90K | Missense Mutation (SNP) | VAF 47/396 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SKOR2 | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- SLAIN1 | c.1484G>T p.G495V (on ENST00000466548; = p.G232V on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); called by muse, mutect2
- SLC45A3 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- SLC4A8 | c.1594C>T p.L532F | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMAD7 | c.814A>T p.R272* | Nonsense Mutation (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- SNX25 | c.912C>G p.Y304* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- SNX6 | c.1252A>G p.T418A (on ENST00000652385; = p.T290A on NM_021249.5) | Missense Mutation (SNP) | VAF 124/500 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- SOGA3 | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2
- SORCS3 | c.1929G>C p.W643C | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOX8 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SPATA7 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 96/423 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- STIM1 | c.532G>C p.V178L | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS1R2 | c.1557C>A p.D519E | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- TBCK | c.863G>T p.S288I (on ENST00000273980 / NM_001163436.4; = p.S225I on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TDRD15 | c.1971A>T p.L657F | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- THSD7B | c.2128G>C p.V710L | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, varscan2
- TNRC18 | c.6766G>C p.D2256H | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TRPM4 | c.613-2A>G p.X205_splice | Splice Site (SNP) | VAF 168/576 reads (29%) | called by muse, mutect2, varscan2
- TTLL5 | c.934+1G>T p.X312_splice | Splice Site (SNP) | VAF 26/397 reads (7%) | called by muse, mutect2
- UBXN4 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- UCP1 | c.846C>A p.N282K | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- VPS9D1 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- XIRP2 | c.6104G>T p.W2035L (on ENST00000628543; = p.W2210L on NM_152381.6) | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC20 | c.200_202del p.W67del | In Frame Del (DEL) | VAF 34/337 reads (10%) | called by mutect2, pindel, varscan2
- ZNF488 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF521 | c.1155G>T p.R385S | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ZNF578 | c.1607A>C p.E536A | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF592 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF74 | c.1042A>T p.S348C | Missense Mutation (SNP) | VAF 92/373 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- ZNF768 | c.1448G>T p.R483L | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ZNF770 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC007040.2 | c.21G>C p.L7= | Silent (SNP) | VAF 44/388 reads (11%) | called by muse, mutect2, varscan2
- ACAP1 | c.615G>A p.Q205= | Silent (SNP) | VAF 61/217 reads (28%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.546C>A p.I182= | Silent (SNP) | VAF 161/574 reads (28%) | called by muse, mutect2, varscan2
- ASB2 | c.846C>A p.A282= | Silent (SNP) | VAF 44/456 reads (10%) | called by muse, mutect2
- ATCAY | c.240G>T p.L80= | Silent (SNP) | VAF 35/200 reads (18%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.804C>T p.P268= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- BIRC6 | c.8424C>T p.F2808= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs1424431662; called by muse, mutect2, varscan2
- BMP7 | c.1218C>T p.V406= | Silent (SNP) | VAF 132/782 reads (17%) | called by muse, mutect2, varscan2
- BRD8 | c.465G>A p.E155= | Silent (SNP) | VAF 73/311 reads (23%) | catalogued as rs200519958; called by muse, mutect2, varscan2
- BRIP1 | c.3295C>T p.L1099= | Silent (SNP) | VAF 68/349 reads (19%) | called by muse, mutect2, varscan2
- C16orf96 | c.1254C>A p.P418= | Silent (SNP) | VAF 7/33 reads (21%) | called by mutect2, varscan2
- C2orf78 | c.1966C>T p.L656= | Silent (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- CCDC87 | c.457C>A p.R153= | Silent (SNP) | VAF 81/323 reads (25%) | called by muse, mutect2, varscan2
- CCNT2 | c.1776C>T p.D592= | Silent (SNP) | VAF 28/203 reads (14%) | catalogued as rs1471584853, COSV51477112; called by muse, mutect2, varscan2
- CDH7 | c.534G>T p.T178= | Silent (SNP) | VAF 52/375 reads (14%) | called by muse, mutect2, varscan2
- CHAT | c.837C>A p.S279= | Silent (SNP) | VAF 45/295 reads (15%) | called by muse, mutect2, varscan2
- CLEC1A | c.426A>G p.K142= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV59531470; called by muse, mutect2
- CNTN5 | c.2667G>T p.V889= | Silent (SNP) | VAF 22/146 reads (15%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.189C>A p.A63= | Silent (SNP) | VAF 60/295 reads (20%) | catalogued as rs778487279, COSV100662995; called by muse, mutect2, varscan2
- CTNNA2 | c.2235C>G p.A745= | Silent (SNP) | VAF 28/297 reads (9%) | called by muse, mutect2
- CTNNA3 | c.1518C>T p.F506= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV65627569, COSV65628203; called by muse, mutect2, varscan2
- CYP4F22 | c.1437C>T p.S479= | Silent (SNP) | VAF 74/352 reads (21%) | called by muse, mutect2, varscan2
- DYM | c.1500G>C p.L500= | Silent (SNP) | VAF 54/342 reads (16%) | called by muse, mutect2, varscan2
- EIF4E2 | c.123C>A p.P41= | Silent (SNP) | VAF 31/371 reads (8%) | called by muse, mutect2
- ERMAP | c.276G>A p.P92= | Silent (SNP) | VAF 40/480 reads (8%) | catalogued as rs772341251; called by muse, mutect2
- ESPN | c.1050G>A p.P350= | Silent (SNP) | VAF 142/848 reads (17%) | catalogued as rs559886623, COSV100911425; called by muse, varscan2
- FNDC3B | c.1875C>T p.Y625= | Silent (SNP) | VAF 34/333 reads (10%) | called by muse, mutect2, varscan2
- FOXQ1 | c.180G>T p.T60= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1192821113, COSV99723231; called by muse, mutect2, varscan2
- GDF6 | c.675C>A p.P225= | Silent (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- GTPBP8 | c.24G>A p.L8= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as rs748868255, COSV55605933; called by muse, mutect2
- GYS2 | c.870G>T p.V290= | Silent (SNP) | VAF 92/330 reads (28%) | catalogued as rs762852738, COSV99680234; called by muse, mutect2, varscan2
- HGFAC | c.267A>T p.A89= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- INCENP | c.435C>T p.T145= | Silent (SNP) | VAF 111/527 reads (21%) | called by muse, mutect2, varscan2
- IQCH | c.1842T>A p.R614= | Silent (SNP) | VAF 28/199 reads (14%) | called by muse, mutect2, varscan2
- KCNH1 | c.1800G>A p.V600= (on ENST00000271751 / NM_172362.3; = p.V573= on NM_002238.4) | Silent (SNP) | VAF 113/420 reads (27%) | catalogued as COSV55075821; called by muse, mutect2, varscan2
- KCNH4 | c.96C>T p.A32= | Silent (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2
- KIF21B | c.3180C>T p.G1060= | Silent (SNP) | VAF 63/219 reads (29%) | called by muse, mutect2, varscan2
- KLHL32 | c.132C>A p.I44= | Silent (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- LTBP2 | c.630C>T p.R210= | Silent (SNP) | VAF 100/307 reads (33%) | called by muse, mutect2, varscan2
- MAMSTR | c.660C>G p.P220= (on ENST00000318083 / NM_001130915.2; = p.P117= on NM_182574.2) | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV104401625; called by muse, mutect2, varscan2
- MANBA | c.2304C>G p.V768= (on ENST00000642252; = p.V722= on NM_005908.4) | Silent (SNP) | VAF 80/486 reads (16%) | called by muse, mutect2, varscan2
- MAP3K10 | c.792G>A p.A264= | Silent (SNP) | VAF 37/257 reads (14%) | catalogued as rs370341935, COSV99453893; called by muse, mutect2, varscan2
- MDGA2 | c.39C>T p.R13= | Silent (SNP) | VAF 45/242 reads (19%) | called by muse, mutect2, varscan2
- MOV10L1 | c.3504C>T p.N1168= | Silent (SNP) | VAF 123/289 reads (43%) | catalogued as rs773896738; called by muse, mutect2, varscan2
- MPRIP | c.450G>A p.R150= | Silent (SNP) | VAF 107/415 reads (26%) | called by muse, mutect2, varscan2
- MTDH | c.393G>T p.R131= | Silent (SNP) | VAF 73/178 reads (41%) | catalogued as COSV60342412; called by muse, mutect2, varscan2
- MYH13 | c.1959C>A p.A653= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV52846825; called by muse, mutect2
- MYO16 | c.4335G>C p.P1445= | Silent (SNP) | VAF 31/200 reads (16%) | called by muse, mutect2, varscan2
- NAALAD2 | c.564G>T p.G188= | Silent (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- NARS2 | c.702A>G p.Q234= | Silent (SNP) | VAF 47/237 reads (20%) | catalogued as rs1277509460; called by muse, mutect2, varscan2
- NCOR1 | c.2919G>T p.L973= | Silent (SNP) | VAF 43/303 reads (14%) | called by muse, mutect2, varscan2
- NLRP5 | c.1428C>T p.L476= | Silent (SNP) | VAF 27/299 reads (9%) | called by muse, mutect2
- NR0B2 | c.753G>A p.G251= | Silent (SNP) | VAF 50/560 reads (9%) | called by muse, mutect2
- OCSTAMP | c.420C>T p.A140= | Silent (SNP) | VAF 158/619 reads (26%) | called by muse, mutect2, varscan2
- OR4P4 | c.144G>T p.T48= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs745780696, COSV58923895; called by muse, mutect2, varscan2
- OR6J1 | c.495G>T p.L165= | Silent (SNP) | VAF 33/214 reads (15%) | catalogued as rs762138660; called by muse, mutect2, varscan2
- PCDHB16 | c.1362C>A p.T454= | Silent (SNP) | VAF 200/721 reads (28%) | called by mutect2, varscan2
- PCNT | c.1017C>T p.N339= | Silent (SNP) | VAF 155/653 reads (24%) | catalogued as rs200472502, COSV64024753; called by muse, mutect2, varscan2
- PDCD11 | c.1767C>T p.G589= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2
- POU3F1 | c.180G>T p.A60= | Silent (SNP) | VAF 56/184 reads (30%) | called by muse, varscan2
- PPM1L | c.231G>T p.V77= | Silent (SNP) | VAF 152/454 reads (33%) | catalogued as rs769534982; called by muse, mutect2, varscan2
- PRUNE2 | c.5223A>G p.L1741= | Silent (SNP) | VAF 25/147 reads (17%) | called by muse, mutect2, varscan2
- QKI | c.108G>C p.G36= | Silent (SNP) | VAF 73/328 reads (22%) | catalogued as rs1335498723; called by muse, mutect2, varscan2
- RHBDL1 | c.324G>A p.K108= (on ENST00000219551 / NM_001318733.2; = p.K43= on NM_001278720.2) | Silent (SNP) | VAF 53/177 reads (30%) | called by muse, mutect2, varscan2
- RYR2 | c.9105T>A p.I3035= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- SAMD9L | c.1650C>G p.L550= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs1342960658, COSV59079121; called by muse, mutect2, varscan2
- SMYD3 | c.861A>G p.Q287= (on ENST00000490107 / NM_001375962.1; = p.Q228= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/325 reads (9%) | catalogued as rs1334908101, COSV63629810; called by muse, mutect2
- SORCS3 | c.2382G>A p.R794= | Silent (SNP) | VAF 22/183 reads (12%) | called by muse, mutect2, varscan2
- ST18 | c.1152G>A p.P384= | Silent (SNP) | VAF 29/252 reads (12%) | catalogued as rs73587538, COSV52499543; called by muse, mutect2, varscan2
- STAM | c.678C>T p.D226= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- STARD13 | c.2301G>A p.R767= (on ENST00000336934 / NM_001243476.3; = p.R649= on NM_052851.3) | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- STPG2 | c.642G>A p.P214= | Silent (SNP) | VAF 37/229 reads (16%) | catalogued as rs775523692; called by muse, mutect2, varscan2
- TDRD15 | c.3768A>G p.V1256= | Silent (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.198G>T p.P66= | Silent (SNP) | VAF 49/278 reads (18%) | catalogued as rs572485380; called by muse, mutect2, varscan2
- TRIB1 | c.570C>T p.V190= | Silent (SNP) | VAF 27/395 reads (7%) | catalogued as rs1563824348; called by muse, mutect2
- TRPM1 | c.90G>A p.E30= | Silent (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- UBR4 | c.9075C>G p.L3025= | Silent (SNP) | VAF 22/259 reads (8%) | catalogued as rs532939003; called by muse, mutect2
- UGT2A1 | c.327G>A p.Q109= | Silent (SNP) | VAF 40/221 reads (18%) | called by muse, mutect2, varscan2
- WDR35 | c.498G>A p.A166= | Silent (SNP) | VAF 19/212 reads (9%) | catalogued as rs150578416, COSV99853627; called by muse, mutect2
- XKR4 | c.1614C>T p.P538= | Silent (SNP) | VAF 24/244 reads (10%) | called by muse, mutect2
- ZCCHC12 | c.384G>T p.V128= | Silent (SNP) | VAF 88/220 reads (40%) | called by muse, mutect2, varscan2
- ZEB1 | c.693G>C p.V231= | Silent (SNP) | VAF 24/281 reads (9%) | called by muse, mutect2
- ZNF160 | c.390C>G p.S130= | Silent (SNP) | VAF 36/209 reads (17%) | called by muse, mutect2, varscan2
- ZNF226 | c.1206G>T p.R402= | Silent (SNP) | VAF 54/176 reads (31%) | called by muse, mutect2, varscan2
- ZNF587B | c.6G>T p.A2= | Silent (SNP) | VAF 47/314 reads (15%) | called by muse, mutect2, varscan2
- ZNF716 | c.969C>A p.P323= | Silent (SNP) | VAF 36/415 reads (9%) | catalogued as COSV70781574; called by muse, mutect2
- ZNF843 | c.909G>A p.P303= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- ABCC8 | c.1631-47G>T | Intron (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- AK2 | c.-35G>T | 5'UTR (SNP) | VAF 106/509 reads (21%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824976 ins CATC | 5'Flank (INS) | VAF 18/84 reads (21%) | called by mutect2, varscan2
- APOO | c.*30-3142G>T | Intron (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- AR | c.1769-5290G>A | Intron (SNP) | VAF 18/110 reads (16%) | catalogued as COSV65953703; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+1331A>G | Intron (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- CD19 | c.1085-25C>T | Intron (SNP) | VAF 13/122 reads (11%) | catalogued as rs770883566; called by muse, mutect2, varscan2
- CD1B | c.-7C>T | 5'UTR (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100939228; called by muse, mutect2, varscan2
- CEP41 | c.*1352G>T | 3'UTR (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- CHD9 | c.2044-46T>A | Intron (SNP) | VAF 45/205 reads (22%) | called by muse, mutect2, varscan2
- CSMD3 | c.7885+33A>T | Intron (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- CSMD3 | c.-46C>T | 5'UTR (SNP) | VAF 85/241 reads (35%) | called by muse, mutect2, varscan2
- DOCK2 | c.4381-68C>G | Intron (SNP) | VAF 39/254 reads (15%) | called by muse, mutect2, varscan2
- FAM98B | chr15:38484596 A>G | 3'Flank (SNP) | VAF 30/199 reads (15%) | called by muse, varscan2
- FRY | c.*21T>G | 3'UTR (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- GABRB3 | chr15:26773683 G>T | 5'Flank (SNP) | VAF 61/430 reads (14%) | called by muse, mutect2, varscan2
- GFUS | c.147-86A>G | Intron (SNP) | VAF 7/121 reads (6%) | catalogued as rs917245724; called by muse, mutect2
- HSPA7 | n.525C>A | RNA (SNP) | VAF 35/315 reads (11%) | called by muse, mutect2, varscan2
- IGSF22 | c.*112G>A | 3'UTR (SNP) | VAF 38/351 reads (11%) | catalogued as rs1330608820; called by muse, mutect2, varscan2
- LINC00636 | n.435G>A | RNA (SNP) | VAF 21/348 reads (6%) | catalogued as rs781312894; called by muse, mutect2
- MIR513A1 | n.27T>A | RNA (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- MIR6511B2 | chr16:15130338 T>A | 3'Flank (SNP) | VAF 205/778 reads (26%) | called by muse, mutect2, varscan2
- MTCH1 | c.701+611G>T | Intron (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- MTCH1 | c.701+609C>G | Intron (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- OR2L1P | n.704T>C | RNA (SNP) | VAF 68/323 reads (21%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65844T>A | Intron (SNP) | VAF 53/244 reads (22%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163947 C>A | 5'Flank (SNP) | VAF 55/1542 reads (4%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159923 G>T | 5'Flank (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2
- STXBP2 | c.*14C>T | 3'UTR (SNP) | VAF 21/171 reads (12%) | catalogued as rs770860899; called by muse, mutect2, varscan2
- SYT14 | chr1:210163092 C>G | 3'Flank (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- SYT9 | c.-28C>T | 5'UTR (SNP) | VAF 5/51 reads (10%) | catalogued as rs1284351969; called by muse, mutect2
- TRAPPC6B | c.150-14G>T | Intron (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- TTN | c.10360+4423G>A | Intron (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- USP15 | chr12:62417103 G>T | 3'Flank (SNP) | VAF 35/65 reads (54%) | called by muse, mutect2, varscan2
- VN1R10P | n.406G>A | RNA (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- XIST | n.7332C>A | RNA (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- ZNF300P1 | n.1297G>A | RNA (SNP) | VAF 56/303 reads (18%) | catalogued as rs1278918478; called by muse, mutect2, varscan2
- ZNF519 | c.-35T>C | 5'UTR (SNP) | VAF 22/199 reads (11%) | catalogued as rs1312011871; called by muse, mutect2, varscan2
